Surgical pathology report (de-identified scan), TCGA case TCGA-66-2788, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2788-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left lower lobe

Clinical diagnosis and question

Bronchial carcinoma of the left lower lobe.

REPORT ON FINDINGS**Macroscopy**

- 1.) Left lower lobe: inflated, fixed left lower lobe measuring 15 x 10 cm at the base, up to 19.5 cm high, central bronchus resection plane located at the level of bifurcation B6 and the bronchus of the lower group. A staple suture line runs from the hilus in a ventral direction for 2.5 cm, and a staple suture line runs from the hilus in a cranial direction for 3.5 cm. Visceral pleura over S6/S10 in the laterodorsal region shows an area of whitish thickening and flat protrusion and retraction measuring about 6.5 x 3.5 cm. Under this is a firm tumor, max. 5 cm in size, with a vaguely arcuate configuration and central resorption. Peripheral branches of B6, B9 and B10 leading into the tumor. Parenchyma in the tumor margin area partly compacted and pale. Inclusion of vascular branches in the tumor. Rest of parenchyma largely inconspicuous.
- 2.) Lobar LN (station 12) lingula: 1 cm node.
- 3.) Lobar LN (station 12) lower lobe: two nodes, 1.2 cm and 0.7 cm.
- 4.) Interlobar LN (station 11) left: 1.5 cm node.
- 5.) Hilar LN (station 10) left: four nodes between 0.6 cm and 1.5 cm, partly linked together.
- 6.) Pulmonary ligament LN (station 9) left: three nodes between 0.4 cm and 0.9 cm.
- 7.) Low paratracheal LN (station 4) left: 1.7 cm fatty tissue with three nodes between 0.5 cm and 1 cm.
- 8.) Prevascular and retrotracheal LN (station 3) left: three nodes between 0.3 cm and 1.2 cm with surrounding tissue.
- 9.) Subcarinal LN (station 7): 1.5 cm node
- 10.) Paraaortic LN (station 6): 2 cm node with surrounding tissue
- 11.) Subaortic LN (aortopulmonary window) (station 5): 1 cm node with surrounding tissue
- 12.) Hilar LN (station 10) right: two lesioned nodes, 1.5 cm and 1 cm
- 13.) Low paratracheal LN (station 4) right: 1.8 cm node with some surrounding tissue.

Examined:

- 1.) a+b: Tumor with pleura and resorption lacuna, c: tumor with peripheral branch of B9, d: S8 peripheral, e: bronchus and vessel resection margins (tangential),
- 2.) - 13.) All material (in 13.) lamellated)
- 17 blocks, partly Elastica-van Gieson, PAS, diastase-PAS

[page 2 of 2]
Microscopy

Re 1.): Tumor made up of complexes of destructive growth and longer, partly reticulate structures of large atypical epithelia in a multilayered arrangement, repeatedly showing vaguely squamous cell layers, with partly copious eosinophilic or clear, otherwise stained cytoplasm with inclusion of disorganized, anisomorphic nuclei of differing sizes, which also show an enlarged chromatin structure. Nucleoli always prominent. Intercellular gaps and bridges. Isolated small islands of large tumor cells layered rather like onion skins. Occasionally intracellular granular, diastase-digestible, PAS-positive particles and at the same time also small lacunae surrounded by tumor cells and containing diastase-resistant, PAS-positive material, with epithelia here at the margin also visible in parts as bronchioalveolar in nature. Between the tumor cell structures smaller areas of necrosis with partly degraded granulocytes and other cell debris. Then a lacuna formation with abundant necrotic material, here and there remnants of delicate alveolar septa and vessels still visible. Also cholesterol crystal gaps and accumulation of various inflammatory cells. Isolated relatively small vessels in the tumor with tumor cell nests in the lumen. In parts there is a transfer of tumor cell structures to original respiratory epithelium. In the region of cholesterol crystal gaps is an accumulation of large, mostly foamy macrophages also within the very confined, nonoxygenated subpleural (■■■■■■■■■■?) that is still present. In some sections, the tumor also extends directly to the pleura, where the pleural elastic fascia is destroyed and transcended by a few tumor cell nests. Above this, the pleura is markedly enlarged in parts by connective tissue, and in the region of its surface is an accentuated accumulation of inflammatory cells, proliferation of mesenchymal spindle cells and capillary vessels and various inflammatory cells and fibrin plaque. Tumor growth in a central direction, partially surrounding larger vessels with infiltration and partial destruction of a bronchus. Further inflammatory cell infiltrates in the marginal adjacent parenchyma of the lung, where there are interstitial follicular lymphocyte aggregates. Small intraalveolar groups of brown pigmented macrophages. Otherwise essentially preserved alveolar stroma. Only circumscribed lymphocyte-rich infiltrates in the region of the peripheral airways and respiratory bronchioles and alveolar duct. No evidence of tumor at the resection margins of bronchus and large pulmonary vessels. The stroma of the bronchus shows an increase in elastic connective tissue fibers, as well as some chronic inflammatory cells, in part follicularly compressed and also manifest in the region of bronchial glands. A few of them are atrophied. In between or alongside are islets of fatty tissue.

Re 2.) –13.) Some lymph nodes – in particular the larger ones – show an increase in secondary follicles with inclusion of large and partly active germinal centers. Small patches of anthracotic pigment deposits, accumulation of large-cell macrophages, in a few cases also small clusters of epithelioid monocytes. Partial enlargement of the sinus, with larger monocytoïd cells here in places.

EVALUATION

Primary diagnosis/diagnoses:

Large, peripheral, bronchopulmonary, histologically predominantly large-cell, slightly to moderately differentiated, nonkeratinizing squamous cell carcinoma of the left lower lobe of the lung. TNM classification according to this picture pT2 pN0 (0/23) V1 R0. Stage IB. C 34.3; M 8070/3.

Secondary diagnosis/diagnoses:

Partial necrotic tumor change with formation of a relatively large resorption lacuna. Tumor-associated active chronic, partially resorptive inflammation and also locally confined chronic fibrinous, partly already relatively high-grade fibrosing pleuritis. Signs suggestive of a slight respiratory bronchiolitis. Chronic bronchitis and small foci of fatty tissue metaplasia at the bronchus resection margin. Lymph node with slight anthracotic pigment deposits and to some extent marked reactive follicular hyperplasia.

Remark/addendum:

To a minimal extent the carcinoma has invaded the overlying visceral pleura, which is markedly fibrosed here. In a central direction, the tumor has partially infiltrated and destroyed the bronchi of the basal group, the main tumor mass being located in cranial sections of segment 10. Bronchus and vessel resection margins are tumor-free.

Source: NCI Genomic Data Commons file 0c440791-7753-4e40-9cb3-6c06de752f4b (TCGA-66-2788.8EC97DEC-6E60-43C6-97C6-C164F28E3639.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).